Gene-level copy-number profile of specimen HCM-SANG-1317-C20-85A-01D-A80T-32 from HCMI case HCM-SANG-1317-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: G2.
Specimen HCM-SANG-1317-C20-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a47c064c-0afd-4d1e-ae58-66dfd4d3b1e5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1317-C20-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/2da94fa4-6d55-452b-b868-8c33c9d6ac49

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,396; copy number 2: 16,666; copy number 3: 21,419; copy number 4: 11,321; copy number 5: 5,812; copy number 6: 1,358; copy number 7: 742; copy number 8: 195.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 937 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:151,047,751–151,267,479, 14 genes, copy number 7: C1orf56, CDC42SE1, MLLT11, GABPB2, RPS29P29, AL592424.1, SEMA6C, TNFAIP8L2, SCNM1, LYSMD1, TMOD4, VPS72, PIP5K1A, PSMD4.
- chr5:58,198–850,986, 30 genes, copy number 7 (within-gene range 6–7): AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, ZDHHC11.
- chr5:850,291–1,112,063, 10 genes, copy number 7: BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635.
- chr5:4,866,521–4,874,759, 1 gene, copy number 7: AC026415.1.
- chr5:8,525,144–10,522,084, 58 genes, copy number 7: AC091953.1, AC091953.3, AC091953.5, MTND6P2, MTCYBP37, AC091953.2, AC091953.6, AC091953.4, AC091932.4, AC091932.2, AC091932.1, AC091932.3, LINC02199, AC091895.1, AC021088.1, SEMA5A, MIR4636, AC091906.1, AC027335.2, SEMA5A-AS1, AC027335.1, SNHG18, SNORD123, AC026787.1, TAS2R1, LINC02112, RNA5SP177, AC091838.1, LINC02221, AC091905.2, AC091905.3, AC091905.1, AC091905.4, AC034229.1, AC034229.6, AC034229.5, AC034229.2, AC034229.3, AC034229.4, ATPSCKMT, AC012640.1, CCT5, AC012640.4, AC012640.3, CMBL, Y_RNA, Y_RNA, AC012640.5, AC012640.2, MARCHF6, ROPN1L-AS1, ROPN1L, MIR6131, LINC01513, RPL30P7, AC092336.1, LINC02212, LINC02213.
- chr5:12,297,399–13,190,677, 7 genes, copy number 7: RNU6-679P, AC106771.1, LINC01194, AC106794.2, AC106794.1, LINC02220, AC016553.1.
- chr5:13,553,654–13,553,966, 1 gene, copy number 7: NENFP3.
- chr5:14,143,342–15,496,353, 21 genes, copy number 7: TRIO, AC016549.1, OTULINL, AC010627.1, CCT6P2, EEF1A1P13, AC010491.1, OTULIN, ANKH, AC010491.2, RBBP4P1, MIR4637, AC016575.1, UQCRBP3, HNRNPKP5, SEPHS2P1, U8, LINC02149, MARK2P5, AC114964.2, AC114964.1.
- chr5:16,373,361–16,617,058, 4 genes, copy number 7: LINC02150, AC020980.1, ZNF622, RETREG1.
- chr5:16,617,225–16,623,095, 2 genes, copy number 7: AC022113.1, Y_RNA.
- chr10:80,394–254,637, 4 genes, copy number 7: IL9RP2, ZMYND11, AL713922.2, RNA5SP297.
- chr10:743,992–1,132,384, 9 genes, copy number 7: AL157709.1, LARP4B, AL359878.2, AL359878.1, GTPBP4, IDI2, IDI2-AS1, IDI1, WDR37.
- chr10:1,989,076–2,015,005, 1 gene, copy number 7: LINC00700.
- chr10:2,305,083–6,580,301, 86 genes, copy number 7 (broad region; genes not listed).
- chr10:8,656,716–13,668,445, 72 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr10:14,518,557–16,005,923, 28 genes, copy number 7: FAM107B, AL158168.1, RNA5SP302, RPSAP7, CDNF, AC069544.2, HSPA14, AC069544.1, SUV39H2, DCLRE1C, MEIG1, OR7E110P, OR7E26P, OR7E115P, DCLRE1CP1, OLAH, ACBD7, GAPDHP45, RPP38-DT, RPP38, NMT2, PPIAP30, AL590365.1, FAM171A1, AL607028.1, ITGA8, MINDY3, AL358033.1.
- chr10:17,137,336–35,898,963, 309 genes, copy number 7 (broad region; genes not listed).
- chr16:28,973,962–32,380,049, 259 genes, copy number 7–8 (broad region; genes not listed).
- chr16:51,553,436–52,943,464, 21 genes, copy number 7: HNRNPA1P48, RN7SKP142, LINC01571, C16orf97, AC009039.1, AC009039.2, LINC00919, LINC02180, AC007333.2, AC007333.1, CASC22, TOX3, AC007490.1, CASC16, AC026462.5, AC026462.3, AC026462.2, AC026462.4, AC026462.1, PHBP21, AC007346.1.

Autosomal genes at a single copy (total copy number 1): 1,396. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
